Somatic mutation profile of tumor specimen TARGET-10-PATIBE-09A (aliquot TARGET-10-PATIBE-09A-01D) from TARGET case TARGET-10-PATIBE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.2 years (4,106 days).
Specimen TARGET-10-PATIBE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9605e3b8-7657-41ec-82d3-09e58d82c249.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATIBE-10A (Blood Derived Normal), aliquot TARGET-10-PATIBE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c145d36-69bd-4463-89cc-3e06428b8239

The open-access MAF lists 26 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Intron 2, Frame Shift Ins 2, RNA 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHDC1 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1010737698, COSV55941648; called by muse, mutect2, varscan2
- ARHGAP31 | c.3711C>A p.S1237R | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV51796846, COSV51799896; called by muse, mutect2, varscan2
- CDH3 | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs368064604, COSV50576830; called by muse, mutect2, varscan2
- CFAP46 | c.5720C>A p.A1907E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.095); catalogued as COSV54153984; called by muse, mutect2, varscan2
- EVC2 | c.3157G>A p.D1053N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs746187559, COSV60403869; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD5 | c.1496A>T p.E499V | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53253631; called by muse, mutect2, varscan2
- KLF9 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV65808258; called by muse, mutect2, varscan2
- KMT2A | c.11746C>T p.R3916W | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63293171; called by muse, mutect2, varscan2
- LILRB1 | c.632G>A p.R211H (on ENST00000427581; = p.R175H on NM_006669.6) | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs112916853, COSV61116962, COSV61117136, COSV61121229; called by muse, mutect2, varscan2
- TNS1 | c.2215C>A p.P739T | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV50777441; called by muse, mutect2, varscan2
- KIF21A | c.2965_2966insCACGGAGA p.M989Tfs*7 (on ENST00000361418 / NM_001378440.1; = p.M976Tfs*7 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 33/104 reads (32%) | called by mutect2, pindel, varscan2
- MAP1B | c.2932G>A p.A978T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- NOTCH1 | c.7398_7399insAGGGACCG p.S2467Rfs*13 | Frame Shift Ins (INS) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- PPP4R3C | c.1052G>T p.S351I | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TRPC7 | c.1148G>A p.S383N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.21); called by muse, mutect2
- DNAH11 | c.7887C>A p.G2629= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV60982567; called by muse, mutect2
- GABRQ | c.123C>T p.P41= | Silent (SNP) | VAF 53/99 reads (54%) | catalogued as rs782201190, COSV100941443; called by muse, mutect2, varscan2
- GRM3 | c.1834C>A p.R612= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV64470299, COSV64470519; called by muse, mutect2, varscan2
- OR5B21 | c.921C>T p.P307= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs1320148796; called by muse, mutect2, varscan2
- PLCH1 | c.4893C>T p.T1631= (on ENST00000340059 / NM_001130960.2; = p.T1623= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/96 reads (54%) | catalogued as rs201236953, COSV58193002; called by muse, mutect2, varscan2
- SLC7A14 | c.747C>T p.H249= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs200644960; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM63C | c.2049C>T p.H683= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs762495465, COSV53610314; called by muse, mutect2, varscan2
- AL713998.1 | n.16C>T | RNA (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- CRYAB | c.324+67C>A | Intron (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- HJURP | c.403-130G>A | Intron (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- HOXB1 | c.*62A>T | 3'UTR (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2
